Somatic mutation profile of tumor specimen HCM-BROD-0025-C16-01A (aliquot HCM-BROD-0025-C16-01A-01D-A80U-36) from HCMI case HCM-BROD-0025-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.7 years (26,928 days).
Specimen HCM-BROD-0025-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6b6847-3786-425c-8b39-b1154e32db55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0025-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0025-C16-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a428f201-cd49-493b-a74a-4f1bad47c0f3

The open-access MAF lists 1,020 somatic variants for this specimen: 725 protein-altering or splice-affecting, 246 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 529, Silent 246, Frame Shift Del 128, Frame Shift Ins 29, Intron 27, Nonsense Mutation 27, 3'UTR 8, Splice Region 6, 5'Flank 6, In Frame Del 5, 3'Flank 4, 5'UTR 2.

Variants (750 of 1,020; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 150/480 reads (31%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, varscan2
- C19orf12 | c.395T>A p.L132Q (on ENST00000392278 / NM_001031726.3; = p.L121Q on NM_031448.6) | Missense Mutation (SNP) | VAF 211/740 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs387907173, CM131542; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.807del p.T270Qfs*2 | Frame Shift Del (DEL) | VAF 98/312 reads (31%) | catalogued as rs1569278313; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 242/794 reads (30%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 80/308 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 170/557 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA2 | c.2272G>A p.V758M (on ENST00000614293; = p.V728M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1311006535; called by muse, mutect2
- ABCA3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 126/441 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs148726153; called by muse, mutect2, varscan2
- ABCB4 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 98/374 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV55935898; called by muse, mutect2, varscan2
- ABHD16B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 177/817 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs765475843; called by muse, mutect2, varscan2
- ACSL6 | c.691G>A p.E231K (on ENST00000379240; = p.E256K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/672 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV57297051; called by muse, mutect2
- ADAMTS12 | c.200dup p.L67Ffs*39 | Frame Shift Ins (INS) | VAF 100/346 reads (29%) | catalogued as rs1181397524; called by mutect2, varscan2
- ADAMTS2 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 157/502 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs758048360, COSV52388571; called by muse, mutect2, varscan2
- ADAT3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 111/774 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs760364157; called by muse, mutect2, varscan2
- ADCY3 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 182/679 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs371180476; called by muse, mutect2, varscan2
- ADPRHL1 | c.1230dup p.S411Efs*206 | Frame Shift Ins (INS) | VAF 192/651 reads (29%) | catalogued as rs1299889061; called by mutect2, varscan2
- AGPS | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as COSV51562087; called by muse, mutect2, varscan2
- AHRR | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 127/479 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as rs202003342; called by muse, mutect2, varscan2
- ALKBH4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 161/667 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1272307282; called by muse, mutect2, varscan2
- ALOX12B | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221632429, COSV59875270; called by muse, varscan2
- ANKRD30B | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as COSV62825843; called by muse, varscan2
- ANKUB1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 140/471 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774131451, COSV67167718; called by muse, mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 180/678 reads (27%) | catalogued as COSV50178856; called by mutect2, varscan2
- ANTXR2 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1329770281; called by muse, mutect2, varscan2
- APC | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 83/308 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs746592911, COSV57336720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 255/597 reads (43%) | catalogued as rs766947286, COSV62372295; called by muse, mutect2, varscan2
- APEX2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs866601451, COSV66624500; called by muse, mutect2, varscan2
- APMAP | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as rs746407755; called by muse, mutect2
- APOE | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 26/870 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1249355043; called by muse, mutect2
- ARHGAP44 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs780981692; called by muse, mutect2, varscan2
- ARID1A | c.3404C>A p.P1135H | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61375272; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 100/464 reads (22%) | catalogued as COSV61372705; called by mutect2, varscan2
- ARRDC1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 286/681 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1388907024; called by muse, mutect2, varscan2
- ARRDC2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 171/653 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1488152915; called by muse, mutect2, varscan2
- ASMTL | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 116/970 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs368558385, COSV67244975; called by muse, mutect2, varscan2
- ATAD3A | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 123/466 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867354699, COSV59232181; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 102/450 reads (23%) | catalogued as rs766479650; called by mutect2, varscan2
- ATM | c.8762C>T p.T2921M | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs730881329, COSV53726751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.2687G>A p.R896H (on ENST00000545399 / NM_001256214.2; = p.R883H on NM_152296.5) | Missense Mutation (SNP) | VAF 148/534 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs782627825, COSV100132518; called by muse, mutect2, varscan2
- ATP2A2 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs1296425781; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- BAHCC1 | c.5473C>T p.R1825C | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs782228993; called by muse, mutect2
- BCAT2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 166/573 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV60273040; called by muse, mutect2, varscan2
- BDP1 | c.4309C>T p.R1437* | Nonsense Mutation (SNP) | VAF 149/574 reads (26%) | catalogued as rs777807458; called by muse, mutect2, varscan2
- BPIFB4 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 328/696 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778947397, COSV64950766; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs762988845; called by mutect2, varscan2
- C5 | c.4323C>T p.A1441= | Splice Region (SNP) | VAF 47/131 reads (36%) | catalogued as rs773359384; called by muse, mutect2, varscan2
- CACNA1A | c.7145G>A p.R2382Q | Missense Mutation (SNP) | VAF 250/778 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1374236989; called by muse, varscan2
- CACNA1A | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 149/577 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.369); catalogued as rs1057518589; ClinVar: uncertain significance; called by muse, varscan2
- CAMSAP2 | c.2447C>T p.A816V (on ENST00000236925 / NM_001297707.2; = p.A805V on NM_203459.3) | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.359); catalogued as rs780764806; called by muse, mutect2, varscan2
- CASKIN1 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 206/654 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1350909348; called by muse, mutect2, varscan2
- CASP3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs146955836; called by muse, mutect2, varscan2
- CATSPER1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 79/406 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs766294676; called by muse, mutect2, varscan2
- CBARP | c.16A>G p.T6A (on ENST00000382477; = p.T12A on NM_152769.3) | Missense Mutation (SNP) | VAF 262/886 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs143196649; called by muse, varscan2
- CCDC105 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 133/480 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs755625395, COSV99479903; called by muse, mutect2, varscan2
- CCDC148 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs140798767; called by muse, mutect2, varscan2
- CCDC150 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761071958, COSV55877654; called by muse, mutect2, varscan2
- CCDC166 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 38/678 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.056); catalogued as rs1554616885; called by muse, mutect2
- CCDC168 | c.3244del p.S1082Vfs*8 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as COSV70555694; called by mutect2, varscan2
- CCDC92 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 30/876 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs137881473; called by muse, mutect2
- CD163L1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); catalogued as COSV58020915; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 53/221 reads (24%) | catalogued as rs773911500; called by mutect2, varscan2
- CDH13 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 110/402 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1193690872, COSV51786661, COSV51799691; called by muse, mutect2, varscan2
- CDKAL1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as rs1188216906; called by muse, varscan2
- CDNF | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 76/526 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs763176247; called by muse, mutect2, varscan2
- CEP68 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 128/457 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV53125736; called by muse, mutect2, varscan2
- CFAP47 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 56/240 reads (23%) | catalogued as COSV52885562, COSV99934429; called by muse, mutect2, varscan2
- CHD8 | c.2098C>T p.R700C (on ENST00000646647 / NM_001170629.2; = p.R421C on NM_020920.4) | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868527880, COSV67869986; called by muse, mutect2, varscan2
- CHGA | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 148/522 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs971618106; called by muse, mutect2, varscan2
- CKAP2 | c.1879C>T p.R627C (on ENST00000378037 / NM_001098525.2; = p.R626C on NM_018204.5) | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748867286, COSV51623279; called by muse, mutect2, varscan2
- CLDN10 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 112/452 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1419354135, COSV65300236; called by muse, mutect2, varscan2
- CLDN6 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs535126754; called by muse, mutect2, varscan2
- CLDN6 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 164/597 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs528018513; called by muse, mutect2, varscan2
- CLDN9 | c.537dup p.L180Afs*104 | Frame Shift Ins (INS) | VAF 154/570 reads (27%) | catalogued as rs763852712; called by mutect2, varscan2
- CLEC18C | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 69/528 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1042778645; called by muse, varscan2
- CLIP2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 155/524 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs374499437; called by muse, mutect2, varscan2
- CNGA2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 118/383 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747754116, COSV61704268, COSV61704381; called by muse, mutect2, varscan2
- COL20A1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as rs1255629105; called by muse, mutect2, varscan2
- COL4A4 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1466061793; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 128/390 reads (33%) | catalogued as rs771066852; called by mutect2, varscan2
- COL9A2 | c.1371C>T p.G457= | Splice Region (SNP) | VAF 40/942 reads (4%) | catalogued as rs1244724713; called by muse, mutect2
- COL9A2 | c.1242dup p.G415Rfs*29 | Frame Shift Ins (INS) | VAF 134/526 reads (25%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, varscan2
- CROCC2 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 153/599 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.338); catalogued as rs568734799; called by muse, mutect2, varscan2
- CRP | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 134/502 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs748954737, COSV54814395; called by muse, mutect2, varscan2
- CSMD1 | c.8707G>T p.D2903Y (on ENST00000520002; = p.D2902Y on NM_033225.6) | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59321665; called by muse, mutect2, varscan2
- CTNNBL1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 132/662 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs764060163, COSV63743564, COSV63745558; called by muse, mutect2, varscan2
- CX3CL1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 160/544 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs558560542, COSV99136284; called by muse, mutect2, varscan2
- CYP11B2 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 87/539 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1348178413, COSV59995180; called by muse, mutect2, varscan2
- CYP4F2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs61755872; called by muse, mutect2, varscan2
- CYP4F22 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 166/660 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs773295754, COSV99512903; called by muse, mutect2, varscan2
- CYP7B1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100040356; called by muse, mutect2, varscan2
- DAND5 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 167/629 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376389047; called by muse, mutect2, varscan2
- DCAF8L2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 153/458 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1163117597; called by muse, mutect2, varscan2
- DGAT2L6 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs142841201; called by muse, mutect2, varscan2
- DGKH | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs764666256; called by muse, mutect2, varscan2
- DNAH9 | c.11733G>T p.K3911N | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52346618; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 38/143 reads (27%) | catalogued as rs750262341; called by mutect2, varscan2
- DPF1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 126/513 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs1004539756; called by muse, mutect2, varscan2
- DPPA3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs775271861, COSV61503365; called by muse, mutect2, varscan2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- DSEL | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs777465144; called by muse, mutect2, varscan2
- EFCC1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 111/607 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144132700; called by muse, mutect2, varscan2
- EIF3A | c.2369G>T p.R790L | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772554138, COSV64960718; called by muse, mutect2, varscan2
- EP400 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 234/763 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs146452426; called by muse, mutect2, varscan2
- EPB41L2 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765521376, COSV61356920; called by muse, mutect2
- EPB41L3 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200869858; called by muse, mutect2, varscan2
- EPG5 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766875773, COSV56348725; called by muse, mutect2, varscan2
- EPHA1 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV51976747; called by muse, mutect2, varscan2
- ERC1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 104/477 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs771123374; called by muse, mutect2, varscan2
- ERGIC3 | c.717C>T p.N239= | Splice Region (SNP) | VAF 125/660 reads (19%) | catalogued as rs201199310; called by muse, mutect2, varscan2
- ESD | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1270161272; called by muse, mutect2
- ESPNL | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 46/708 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147767227, COSV58033944; called by muse, mutect2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 92/350 reads (26%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM184B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 121/581 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs977021514, COSV99401932; called by muse, mutect2, varscan2
- FAM189A2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748266947; called by muse, mutect2, varscan2
- FAM222A | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 153/609 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs376914566; called by muse, mutect2, varscan2
- FAM91A1 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs769171490, COSV58235667; called by muse, mutect2, varscan2
- FBLN2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 142/476 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369694803; called by muse, varscan2
- FBN1 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as COSV57323300; called by muse, mutect2, varscan2
- FBXW10 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1298042791; called by muse, mutect2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 92/348 reads (26%) | catalogued as rs750132652; called by mutect2, varscan2
- FCRLA | c.775G>A p.G259R (on ENST00000367959; = p.G236R on NM_032738.4) | Missense Mutation (SNP) | VAF 135/512 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140120225; called by muse, mutect2, varscan2
- FGFBP2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488358811; called by muse, mutect2, varscan2
- FLT3 | c.2659A>G p.N887D | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54060725; called by muse, mutect2, varscan2
- FLT4 | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV56103230; called by muse, mutect2, varscan2
- FMN2 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 197/589 reads (33%) | catalogued as rs780928554, COSV60425069; called by muse, mutect2, varscan2
- FPR1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs547228145, COSV59053059; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 172/468 reads (37%) | catalogued as rs35659462; called by mutect2, varscan2
- FTSJ3 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 50/561 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV59563841; called by muse, mutect2
- FUT3 | c.422del p.P141Lfs*94 | Frame Shift Del (DEL) | VAF 58/460 reads (13%) | catalogued as rs768440398; called by mutect2, varscan2
- GAB4 | c.153del p.E52Rfs*4 | Frame Shift Del (DEL) | VAF 110/388 reads (28%) | catalogued as rs764879401, COSV68754102; called by mutect2, varscan2
- GAD2 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753672041, COSV52161355, COSV99035167; called by muse, mutect2, varscan2
- GALNT2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 173/714 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.077); catalogued as rs1327732533, COSV64192684; called by muse, mutect2, varscan2
- GALNT9 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 113/514 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs1237415738; called by muse, mutect2, varscan2
- GAPVD1 | c.1304T>C p.M435T | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV52920608; called by muse, mutect2, varscan2
- GATB | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV56130377; called by muse, mutect2, varscan2
- GEMIN5 | c.2176del p.S726Vfs*24 | Frame Shift Del (DEL) | VAF 59/196 reads (30%) | catalogued as COSV53564949; called by mutect2, varscan2
- GGT1 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 47/496 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs45445196; called by muse, mutect2, varscan2
- GJB4 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs778397300, COSV58355656, COSV58357162; called by muse, mutect2, varscan2
- GLI2 | c.2033C>T p.T678M (on ENST00000361492 / NM_001374353.1; = p.T695M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/513 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150858529, COSV58042900; called by muse, mutect2, varscan2
- GLIS2 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 225/787 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52110075; called by muse, mutect2, varscan2
- GM2A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 127/525 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs104893892, CM930346; called by muse, mutect2, varscan2
- GP2 | c.766C>A p.L256M (on ENST00000381362 / NM_001007240.3; = p.L253M on NM_001502.4) | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390353891, COSV56894286; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 112/452 reads (25%) | catalogued as rs759103894; called by mutect2, varscan2
- GRAMD1B | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 167/575 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV59204216, COSV99074529; called by muse, mutect2, varscan2
- GRID2IP | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 171/693 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs942337846; called by muse, mutect2, varscan2
- GSE1 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 73/587 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773249489; called by muse, mutect2, varscan2
- GUCY2F | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 113/377 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1477248854, COSV54297893; called by muse, mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 55/469 reads (12%) | catalogued as CM105646; called by mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 120/465 reads (26%) | catalogued as COSV55172930; called by mutect2, varscan2
- HDAC7 | c.1577C>T p.S526L (on ENST00000427332; = p.S565L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs150532318; called by muse, mutect2, varscan2
- HEATR1 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs778570394, COSV63982589; called by muse, mutect2, varscan2
- HGFAC | c.1800dup p.P601Afs*20 | Frame Shift Ins (INS) | VAF 118/395 reads (30%) | catalogued as rs770643102; called by mutect2, varscan2
- HGSNAT | c.693G>A p.W231* | Nonsense Mutation (SNP) | VAF 168/622 reads (27%) | catalogued as COSV65536005; called by muse, mutect2, varscan2
- HIVEP3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 132/531 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751390922, COSV56018437; called by muse, mutect2, varscan2
- HLA-B | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 252/664 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as COSV69523218; called by muse, varscan2
- HOXB4 | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100203708; called by muse, mutect2, varscan2
- HSD17B14 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 304/997 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1400589983, COSV99622656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSD3B2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs587711475; called by muse, mutect2, varscan2
- HSPA12A | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1554881213; called by muse, mutect2, varscan2
- HSPG2 | c.6010C>T p.R2004C | Missense Mutation (SNP) | VAF 143/517 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs777591903, COSV101020332, COSV65975083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFFO2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1274576588, COSV100841950; called by muse, mutect2, varscan2
- IFI16 | c.1873A>G p.T625A (on ENST00000295809 / NM_001364867.2; = p.T569A on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV99857154; called by muse, mutect2, varscan2
- IL12RB2 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 43/229 reads (19%) | catalogued as rs771578695, COSV52027175; called by muse, mutect2, varscan2
- IL1RAPL2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs780226679; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 95/328 reads (29%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- IMMP2L | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.966); catalogued as rs1198333573; called by muse, mutect2, varscan2
- INO80 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1466180067, COSV62739938; called by muse, mutect2, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 40/179 reads (22%) | catalogued as rs768918635; called by mutect2, varscan2
- IQCE | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 178/555 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs774115233; called by muse, mutect2, varscan2
- IRS4 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 138/432 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64535612; called by muse, mutect2, varscan2
- IRX6 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 72/614 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464206859; called by muse, mutect2, varscan2
- ISX | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147806898; called by muse, mutect2, varscan2
- JAK3 | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 179/636 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71687414; called by muse, mutect2, varscan2
- KCNB2 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 105/385 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1225497498, COSV73049361; called by muse, mutect2, varscan2
- KCNH3 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 90/990 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1309577705; called by muse, mutect2
- KCNH8 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1431768344, COSV60460323; called by muse, mutect2, varscan2
- KCNQ5 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV100571624; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 159/511 reads (31%) | catalogued as rs782541016; called by mutect2, varscan2
- KIAA0100 | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 126/425 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.969); catalogued as rs757697591, COSV66492040; called by muse, mutect2, varscan2
- KIAA1210 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.362); catalogued as rs368835636, COSV68178005; called by muse, mutect2, varscan2
- KIAA1217 | c.4748C>T p.A1583V | Missense Mutation (SNP) | VAF 142/505 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773862720; called by muse, mutect2, varscan2
- KIF18B | c.2452+8G>A | Splice Region (SNP) | VAF 78/287 reads (27%) | catalogued as rs530427949, COSV100192338; called by muse, mutect2, varscan2
- KIF26B | c.6010C>T p.R2004* | Nonsense Mutation (SNP) | VAF 110/530 reads (21%) | catalogued as COSV63653044; called by muse, mutect2
- KIF7 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs763584371, COSV67997530; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 45/266 reads (17%) | catalogued as rs756907493; called by mutect2, varscan2
- KLHL33 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 170/626 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs996119781, COSV60727732; called by muse, mutect2, varscan2
- KMT2A | c.8422C>T p.R2808C | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs782078199, COSV100628180; called by muse, mutect2
- KMT2C | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs764909368, COSV51493691; called by muse, varscan2
- KRT1 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 124/683 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs754534861; called by muse, varscan2
- LAMC2 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs74445945; called by muse, mutect2, varscan2
- LCMT2 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 153/435 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs903537988; called by muse, mutect2, varscan2
- LCT | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544049; called by muse, mutect2, varscan2
- LDHD | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 128/433 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs139673012; called by muse, mutect2, varscan2
- LDLRAD1 | c.445del p.D149Tfs*6 | Frame Shift Del (DEL) | VAF 90/342 reads (26%) | catalogued as COSV64956147; called by mutect2, varscan2
- LEPR | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs752809639; called by muse, mutect2, varscan2
- LGI2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs144272338; called by muse, mutect2, varscan2
- LLGL1 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as rs781433997, COSV57499533; called by muse, mutect2, varscan2
- LMTK3 | c.2182G>C p.A728P | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1465136841; called by mutect2, varscan2
- LRIT2 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 137/490 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs766565567; called by muse, mutect2
- LRRC4B | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 95/761 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.72); catalogued as rs1303710203; called by muse, mutect2, varscan2
- LTBP4 | c.4361C>T p.P1454L (on ENST00000308370 / NM_001042544.1; = p.P1417L on NM_003573.2) | Missense Mutation (SNP) | VAF 243/818 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs190277382, COSV99180973; called by muse, mutect2, varscan2
- MAGEB17 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 154/386 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1250947733, COSV61557263; called by muse, mutect2, varscan2
- MAP1A | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 130/462 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs192228146; called by muse, mutect2, varscan2
- MAPK12 | c.1075del p.A359Pfs*19 | Frame Shift Del (DEL) | VAF 138/392 reads (35%) | catalogued as rs1184072475; called by mutect2, varscan2
- MAPK3 | c.32del p.G11Afs*21 | Frame Shift Del (DEL) | VAF 98/288 reads (34%) | catalogued as COSV53772256; called by mutect2, varscan2
- MATN3 | c.1159dup p.T387Nfs*6 | Frame Shift Ins (INS) | VAF 27/210 reads (13%) | catalogued as rs1203662025; called by mutect2, varscan2
- MBP | c.911G>A p.R304H (on ENST00000355994 / NM_001025101.2; = p.R186H on NM_002385.3) | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1051415090; called by muse, mutect2, varscan2
- MCM10 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 131/450 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1018504619; called by muse, mutect2, varscan2
- MCM7 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332080071; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 158/573 reads (28%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- METTL3 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1336492472, COSV52971692; called by muse, mutect2, varscan2
- MLLT1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 137/518 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs759257032, COSV53129465, COSV99398183; called by muse, mutect2, varscan2
- MMP2 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772654963; called by muse, mutect2, varscan2
- MPP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 170/301 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782521600, COSV65728662; called by muse, mutect2, varscan2
- MSH4 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs866210811, COSV54196342; called by muse, mutect2, varscan2
- MTNR1B | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 154/518 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV57068295; called by muse, mutect2, varscan2
- MTSS2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 79/771 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs747980657, COSV58698595; called by muse, mutect2, varscan2
- MUC16 | c.13886C>T p.A4629V | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs372648706; called by muse, mutect2, varscan2
- MYOCD | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 166/580 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs771058548, COSV58497700; called by muse, mutect2, varscan2
- MYT1L | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs765680020, COSV67721562; called by muse, varscan2
- MYT1L | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 105/401 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs754747899, COSV67706497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALADL2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760832134, COSV70795029; called by muse, mutect2, varscan2
- NAGA | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 23/620 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1569458798, COSV67170180; called by muse, mutect2
- NBEA | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1165053722, COSV59813225; called by muse, mutect2, varscan2
- NCDN | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 165/578 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs753953315, COSV57846751; called by muse, mutect2, varscan2
- NEDD4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 111/435 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs774933057, COSV101436641; called by muse, mutect2, varscan2
- NEURL1B | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 152/466 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.079); catalogued as rs1460619648; called by muse, mutect2, varscan2
- NID1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 135/467 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51621005; called by muse, mutect2, varscan2
- NID2 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53495542; called by muse, mutect2, varscan2
- NMUR2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 133/507 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs200145877, COSV54919748; called by muse, mutect2, varscan2
- NTAN1 | c.831dup p.H278Tfs*13 | Frame Shift Ins (INS) | VAF 100/383 reads (26%) | catalogued as rs780770021; called by mutect2, varscan2
- OCA2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 131/497 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1390458631, COSV62355676; called by muse, mutect2, varscan2
- OCM2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 128/506 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777688959, COSV57535046; called by muse, mutect2, varscan2
- OGDHL | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201783448, COSV65103304; called by muse, mutect2, varscan2
- OR2G3 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180756; called by muse, mutect2, varscan2
- OR4X1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1441527199, COSV60722405; called by muse, mutect2, varscan2
- OR51T1 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 87/367 reads (24%) | catalogued as COSV59026831; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 83/260 reads (32%) | catalogued as rs762677866, COSV100263457; called by mutect2, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs1254479213; called by mutect2, varscan2
- OR5AR1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs758374441, COSV57254483; called by muse, mutect2, varscan2
- OR7C2 | c.535dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 76/254 reads (30%) | catalogued as rs747041500; called by mutect2, varscan2
- OR8J2 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs749563072; called by muse, mutect2
- OSBPL9 | c.2110_2112del p.E704del | In Frame Del (DEL) | VAF 82/328 reads (25%) | catalogued as rs1163251306; called by mutect2, varscan2
- OTOG | c.8690G>A p.R2897H | Missense Mutation (SNP) | VAF 165/652 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767373345; called by muse, mutect2
- PAX1 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 167/457 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs752368901, COSV104433357; called by muse, mutect2, varscan2
- PCNX2 | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs754079857, COSV50836927; called by muse, mutect2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 152/550 reads (28%) | catalogued as rs768249210; called by mutect2, varscan2
- PDE10A | c.1670T>C p.L557P | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63101112; called by muse, mutect2, varscan2
- PDIA4 | c.1202G>A p.R401H (on ENST00000286091 / NM_001371244.1; = p.R400H on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/462 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs780487329; called by muse, varscan2
- PDZD2 | c.7694A>G p.Q2565R | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs772823366; called by muse, mutect2, varscan2
- PEDS1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 90/452 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs148820409; called by muse, varscan2
- PFAS | c.3963del p.W1322Gfs*32 | Frame Shift Del (DEL) | VAF 113/473 reads (24%) | catalogued as COSV58980444; called by mutect2, varscan2
- PIEZO2 | c.1377A>G p.S459= | Splice Region (SNP) | VAF 145/319 reads (45%) | catalogued as rs1451736408; called by muse, mutect2, varscan2
- PIK3CD | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 36/760 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs769029561, COSV63132798; called by muse, mutect2
- PKD1L1 | c.5380G>T p.G1794C | Missense Mutation (SNP) | VAF 152/436 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs767372078; called by muse, mutect2, varscan2
- PLA2G4E | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 162/598 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs377526076; called by muse, mutect2, varscan2
- PLK5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 170/616 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1353185384, COSV58292552; called by muse, mutect2, varscan2
- PLOD1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755346019, COSV52143608; called by muse, mutect2, varscan2
- PLXND1 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 155/705 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs937819113; called by muse, mutect2, varscan2
- PNPLA6 | c.2995G>A p.A999T (on ENST00000414982 / NM_001166111.2; = p.A951T on NM_006702.5) | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1369120103; called by muse, mutect2, varscan2
- POLK | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs867423497; called by muse, mutect2, varscan2
- POLR1E | c.340C>A p.P114T (on ENST00000377792 / NM_001282766.1; = p.P52T on NM_022490.4) | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100905429; called by muse, mutect2, varscan2
- PPFIA2 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs376334232; called by muse, mutect2, varscan2
- PPIP5K2 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 40/178 reads (22%) | catalogued as rs550590492, COSV58603146; called by muse, mutect2, varscan2
- PPM1B | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1442639738; called by muse, mutect2, varscan2
- PRR14 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 200/674 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs903673551, COSV54910941; called by muse, varscan2
- PRRT4 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 135/565 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs990410036, COSV71054487; called by muse, mutect2, varscan2
- PTPN23 | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs148181021; called by muse, mutect2, varscan2
- PTPRB | c.3543del p.S1182Pfs*25 | Frame Shift Del (DEL) | VAF 53/262 reads (20%) | catalogued as COSV99716601; called by mutect2, varscan2
- PWP2 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 113/207 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99379647; called by muse, mutect2, varscan2
- PXDN | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as rs777271860; called by muse, mutect2, varscan2
- RBL1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.464); catalogued as rs368117514; called by muse, varscan2
- RBMXL2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 93/379 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1261223303; called by muse, mutect2, varscan2
- RFC1 | c.1940C>T p.A647V (on ENST00000381897 / NM_001363496.2; = p.A646V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/465 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs766790092, COSV62898743; called by muse, mutect2, varscan2
- RIPK2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.359); catalogued as rs1206158101; called by muse, mutect2, varscan2
- RNF175 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 51/183 reads (28%) | catalogued as rs766172106, COSV99923862; called by muse, mutect2, varscan2
- RNF213 | c.12841C>T p.R4281W | Missense Mutation (SNP) | VAF 150/564 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765980348, COSV60400499, COSV60406277; ClinVar: other; called by muse, varscan2
- RNF220 | c.1396A>C p.S466R | Missense Mutation (SNP) | VAF 154/570 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1490747042; called by muse, mutect2, varscan2
- ROBO1 | c.4183G>T p.G1395C | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV71392550; called by muse, mutect2, varscan2
- ROR2 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs745733784; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 114/381 reads (30%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RYR1 | c.4306G>A p.V1436M | Missense Mutation (SNP) | VAF 108/357 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200289457, COSV100614600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 229/818 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, mutect2, varscan2
- RYR3 | c.6710del p.G2237Efs*56 (on ENST00000389232; = p.G2237Efs*57 on NM_001036.6) | Frame Shift Del (DEL) | VAF 66/392 reads (17%) | catalogued as rs751516213; called by mutect2, varscan2
- RYR3 | c.7109G>A p.R2370H (on ENST00000389232; = p.R2371H on NM_001036.6) | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234585541, COSV101212486; called by muse, varscan2
- S1PR2 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 165/611 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs762697846; called by muse, mutect2, varscan2
- SCAP | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs879008440; called by muse, mutect2, varscan2
- SCARB2 | c.961T>G p.S321A | Missense Mutation (SNP) | VAF 29/448 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV53667557; called by muse, mutect2
- SCART1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 164/596 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs928295221; called by muse, mutect2, varscan2
- SCFD2 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs756696217, COSV101189308, COSV101189422; called by muse, mutect2, varscan2
- SDK2 | c.2867C>T p.T956M | Missense Mutation (SNP) | VAF 201/740 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1320889649, COSV66186848; called by muse, mutect2, varscan2
- SEMA6A | c.2637del p.V881Ffs*20 | Frame Shift Del (DEL) | VAF 102/468 reads (22%) | catalogued as rs749631581, COSV56712590; called by mutect2, varscan2
- SETD1A | c.4484G>A p.R1495H | Missense Mutation (SNP) | VAF 43/913 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52680435, COSV52682100; called by muse, mutect2
- SETD1A | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 138/457 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs771053823, COSV52680345; called by muse, mutect2, varscan2
- SEZ6L | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 117/410 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs1211422692, COSV50660109, COSV99962860; called by muse, mutect2, varscan2
- SFXN1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs200390050, COSV58495803; called by muse, mutect2
- SH2D3A | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 187/630 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs1203616918; called by muse, mutect2, varscan2
- SH3BP4 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 191/668 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1246711878; called by muse, mutect2, varscan2
- SH3RF3 | c.1513del p.A505Rfs*3 | Frame Shift Del (DEL) | VAF 168/518 reads (32%) | catalogued as COSV58685960, COSV58695199; called by mutect2, varscan2
- SHCBP1L | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs12568867; called by muse, mutect2
- SHTN1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1309471471; called by muse, mutect2
- SI | c.4043C>T p.T1348M | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs192640245; called by muse, mutect2, varscan2
- SIM1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs374696271, COSV53492540; called by muse, mutect2, varscan2
- SIPA1L2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs1167028057; called by muse, mutect2, varscan2
- SLC12A6 | c.2024G>A p.R675Q (on ENST00000354181 / NM_001365088.1; = p.R624Q on NM_005135.2) | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99271565; called by muse, mutect2, varscan2
- SLC19A1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 63/506 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753215575; called by muse, mutect2, varscan2
- SLC28A2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149379650; called by muse, mutect2, varscan2
- SLC29A4 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 191/661 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs774145930; called by muse, mutect2
- SLC4A11 | c.2450del p.P817Rfs*32 | Frame Shift Del (DEL) | VAF 66/267 reads (25%) | catalogued as CD160132, COSV66260588; called by mutect2, varscan2
- SLITRK4 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022634; called by mutect2, varscan2
- SNX7 | c.80del p.G27Afs*38 | Frame Shift Del (DEL) | VAF 122/432 reads (28%) | catalogued as rs1296656242; called by mutect2, varscan2
- SOX5 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs745428574, COSV58621446; called by muse, mutect2, varscan2
- SP6 | c.461del p.G154Afs*30 | Frame Shift Del (DEL) | VAF 70/659 reads (11%) | catalogued as rs772840452; called by mutect2, varscan2
- SPAG5 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 132/429 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs747402791; called by muse, mutect2, varscan2
- SPATA16 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.509); catalogued as rs778611950, COSV100650911; called by muse, mutect2, varscan2
- SPATS2L | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 151/560 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751577050, COSV62352821; called by muse, mutect2, varscan2
- SPHKAP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60869857; called by muse, mutect2, varscan2
- SPIRE1 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100564139; called by muse, mutect2
- SREBF1 | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 139/430 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as rs753379159; called by muse, mutect2, varscan2
- SRRM2 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 71/616 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs369213768; called by muse, mutect2, varscan2
- STAB2 | c.2278G>A p.G760S | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761459390, COSV101185700; called by muse, mutect2, varscan2
- STAB2 | c.6781G>A p.A2261T | Missense Mutation (SNP) | VAF 113/468 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs147296184; called by muse, mutect2, varscan2
- STK32B | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 117/454 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150966427; called by muse, mutect2, varscan2
- SULF2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 148/806 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1156246531; called by muse, mutect2, varscan2
- SYT3 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 130/477 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs745650170; called by muse, mutect2, varscan2
- TADA3 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1559721021; called by muse, mutect2, varscan2
- TAF4 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 217/933 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs777163384; called by muse, mutect2, varscan2
- TAPBP | c.1013del p.G338Afs*65 | Frame Shift Del (DEL) | VAF 58/542 reads (11%) | catalogued as rs1205258833; called by mutect2, varscan2
- TBC1D16 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 160/535 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs780785193; called by muse, varscan2
- TCF3 | c.1081del p.Q361Rfs*33 | Frame Shift Del (DEL) | VAF 116/455 reads (25%) | catalogued as rs1329397192; called by mutect2, varscan2
- TCIRG1 | c.2376_2379del p.E792Dfs*28 | Frame Shift Del (DEL) | VAF 124/490 reads (25%) | catalogued as rs1189520104; called by mutect2, varscan2
- TDRD5 | c.1005del p.K335Nfs*2 | Frame Shift Del (DEL) | VAF 42/146 reads (29%) | catalogued as rs772423686; called by mutect2, varscan2
- TFE3 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 27/646 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1047731769, COSV100252349; called by muse, mutect2
- TG | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 97/428 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs750196077; called by muse, mutect2, varscan2
- TICAM1 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 117/636 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV50235893; called by muse, mutect2, varscan2
- TIPARP | c.639C>A p.D213E | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV99904042; called by muse, mutect2, varscan2
- TLR7 | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV101027964; called by muse, mutect2
- TNFAIP8L1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 181/625 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1446562090, COSV59420863; called by muse, mutect2, varscan2
- TNKS | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1462401273; called by muse, mutect2, varscan2
- TNNI3K | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 53/234 reads (23%) | catalogued as rs200226149, COSV58562346; called by muse, mutect2, varscan2
- TNS3 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 23/570 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1334788076, COSV100235663, COSV60800954; called by muse, mutect2
- TP53BP2 | c.2033G>A p.G678D (on ENST00000343537 / NM_001031685.3; = p.G549D on NM_005426.2) | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59066067, COSV59067622; called by muse, mutect2, varscan2
- TRIM3 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 69/735 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100624339; called by muse, mutect2
- TRIM35 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 40/680 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs765088471, COSV59522444; called by muse, mutect2
- TRIM64B | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 58/559 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV61693652; called by muse, varscan2
- TRIP10 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 47/612 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs377574912, COSV57573577; called by muse, mutect2
- TSC2 | c.3989C>T p.T1330M | Missense Mutation (SNP) | VAF 137/483 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as rs397515209, CM122780, COSV51920027; ClinVar: uncertain significance / not provided / benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TSPAN4 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 160/555 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754685019; called by muse, varscan2
- U2AF1L4 | c.467G>A p.R156H (on ENST00000412391; = p.R117H on NM_001040425.3) | Missense Mutation (SNP) | VAF 166/620 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs746648207, COSV53075817, COSV53076330; called by muse, mutect2, varscan2
- UBE3B | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1566090452; called by muse, mutect2, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 52/182 reads (29%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- UNKL | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 152/548 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177262207; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRB | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1259052571; called by mutect2, varscan2
- URB2 | c.3716C>T p.T1239M | Missense Mutation (SNP) | VAF 115/463 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199788278; called by muse, varscan2
- UTP25 | c.832del p.L278Sfs*7 | Frame Shift Del (DEL) | VAF 82/318 reads (26%) | catalogued as rs750214623; called by mutect2, varscan2
- VPS13B | c.11014G>A p.A3672T | Missense Mutation (SNP) | VAF 128/459 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs868118584, COSV100662212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS37C | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 150/466 reads (32%) | catalogued as COSV57109253; called by muse, mutect2, varscan2
- VRTN | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 223/690 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330449009, COSV56440995, COSV56441603; called by muse, mutect2, varscan2
- WASF3 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 131/504 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774882598; called by muse, mutect2, varscan2
- WDFY3 | c.6119T>C p.V2040A | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs770417953; called by muse, mutect2, varscan2
- WDR45 | c.331C>T p.R111C (on ENST00000376372 / NM_001029896.2; = p.R112C on NM_007075.3) | Missense Mutation (SNP) | VAF 130/430 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs781985024, COSV59875519; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | catalogued as rs1557951659, COSV63058584; called by mutect2, varscan2
- WNK3 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1230331380, COSV63615299; called by muse, mutect2, varscan2
- ZC3H13 | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 238/986 reads (24%) | catalogued as COSV104387502; called by muse, mutect2, varscan2
- ZDHHC7 | c.831del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 138/542 reads (25%) | catalogued as COSV58214455; called by mutect2, varscan2
- ZEB1 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 132/534 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1041866704; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF316 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 185/606 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs907594755, COSV66385133; called by muse, mutect2, varscan2
- ZNF341 | c.1648T>C p.S550P (on ENST00000375200 / NM_001282935.1; = p.S543P on NM_032819.4) | Missense Mutation (SNP) | VAF 156/724 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs917358675; called by muse, mutect2, varscan2
- ZNF641 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 141/492 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1323322245; called by muse, mutect2, varscan2
- ZNF697 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 191/614 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV101360057; called by muse, mutect2, varscan2
- ZNF700 | c.198del p.K66Nfs*22 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | catalogued as COSV54311507; called by mutect2, varscan2
- ZNF716 | c.23del p.P8Lfs*9 | Frame Shift Del (DEL) | VAF 124/406 reads (31%) | catalogued as COSV70783198; called by mutect2, varscan2
- ZNF831 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 147/628 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs777399101, COSV100926201, COSV64036993; called by muse, varscan2
- ZNF879 | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1216562731; called by muse, mutect2, varscan2
- ZSCAN18 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 132/475 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as COSV53729637, COSV99559285; called by muse, mutect2, varscan2
- ZSWIM2 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs867074464; called by muse, mutect2, varscan2
- ABCC8 | c.889A>T p.R297W | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- ABCC9 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCG2 | c.473del p.N158Tfs*11 | Frame Shift Del (DEL) | VAF 110/405 reads (27%) | called by mutect2, varscan2
- AC011448.1 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 118/442 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AC073111.3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 218/764 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ACIN1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 106/365 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACO1 | c.1396T>C p.Y466H | Missense Mutation (SNP) | VAF 121/329 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ADAMTS10 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 137/573 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ADCK2 | c.1818del p.K607Nfs*57 | Frame Shift Del (DEL) | VAF 147/536 reads (27%) | called by mutect2, varscan2
- ADCY1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 105/434 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADCY4 | c.2563A>G p.I855V | Missense Mutation (SNP) | VAF 120/442 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, varscan2
- ADRB3 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 165/549 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ALMS1 | c.8509C>G p.Q2837E | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- ALOX12 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ALOX15B | c.337del p.A113Rfs*83 | Frame Shift Del (DEL) | VAF 106/359 reads (30%) | called by mutect2, varscan2
- AMH | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 256/977 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AMMECR1L | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- AMMECR1L | c.239A>T p.N80I | Missense Mutation (SNP) | VAF 131/456 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANKDD1B | c.707del p.N236Tfs*20 | Frame Shift Del (DEL) | VAF 88/323 reads (27%) | called by mutect2, varscan2
- ANKRD12 | c.1313dup p.I439Dfs*10 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | called by mutect2, varscan2
- APBA1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); called by muse, mutect2
- APOB | c.12569_12572dup p.S4192* | Nonsense Mutation (INS) | VAF 32/158 reads (20%) | called by mutect2, varscan2
- APOB | c.4489G>A p.A1497T | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APOBR | c.1227G>T p.E409D (on ENST00000431282; = p.E418D on NM_018690.4) | Missense Mutation (SNP) | VAF 22/793 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2
- ARAP3 | c.4397del p.P1466Lfs*16 | Frame Shift Del (DEL) | VAF 128/474 reads (27%) | called by mutect2, varscan2
- ARHGAP26 | c.2095G>C p.V699L | Missense Mutation (SNP) | VAF 171/688 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP32 | c.2267A>G p.H756R (on ENST00000310343 / NM_001378025.1; = p.H407R on NM_014715.4) | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 124/416 reads (30%) | called by mutect2, varscan2
- ARIH2 | c.661-1G>T p.X221_splice | Splice Site (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2, varscan2
- ARNT2 | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- ARRDC5 | c.548G>A p.C183Y (on ENST00000381781; = p.C169Y on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARVCF | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 181/616 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.38); called by muse, varscan2
- ASCC3 | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ATP1A2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 160/570 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BCL2L12 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 94/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRPF3 | c.2425dup p.D809Gfs*21 | Frame Shift Ins (INS) | VAF 136/331 reads (41%) | called by mutect2, varscan2
- C14orf93 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 144/478 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf98 | c.223G>T p.G75* | Nonsense Mutation (SNP) | VAF 118/415 reads (28%) | called by muse, mutect2, varscan2
- C19orf18 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 171/626 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- C1orf54 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- C3 | c.4397A>G p.Y1466C | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- C4orf54 | c.4067C>A p.A1356E | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CACHD1 | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CACNA2D3 | c.1949C>A p.A650E | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CARMIL3 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 116/447 reads (26%) | called by muse, mutect2, varscan2
- CAST | c.1795G>A p.A599T (on ENST00000341926; = p.A682T on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CCDC105 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCDC186 | c.1298del p.N433Tfs*5 | Frame Shift Del (DEL) | VAF 72/266 reads (27%) | called by mutect2, varscan2
- CD58 | c.236del p.N79Ifs*5 | Frame Shift Del (DEL) | VAF 25/216 reads (12%) | called by mutect2, varscan2
- CDCA5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 205/691 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CDH19 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- CDKAL1 | c.1019C>A p.A340D | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CDO1 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 130/490 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CEACAM7 | c.169_171del p.N57del | In Frame Del (DEL) | VAF 76/268 reads (28%) | called by mutect2, varscan2
- CEP170 | c.2977_2980del p.K993Vfs*22 | Frame Shift Del (DEL) | VAF 63/388 reads (16%) | called by mutect2, varscan2
- CES3 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CFAP61 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 74/272 reads (27%) | called by mutect2, varscan2
- CHRND | c.314del p.P105Rfs*77 | Frame Shift Del (DEL) | VAF 105/403 reads (26%) | called by mutect2, varscan2
- CHST2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 24/806 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CLEC18C | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- CLSPN | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CLTC | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.286); called by muse, mutect2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | called by mutect2, varscan2
- CNOT1 | c.5608C>T p.R1870C | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CNOT4 | c.326del p.N109Tfs*6 | Frame Shift Del (DEL) | VAF 68/274 reads (25%) | called by mutect2, varscan2
- COL6A2 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 135/334 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX19 | c.270del p.K90Nfs*4 | Frame Shift Del (DEL) | VAF 104/351 reads (30%) | called by mutect2, varscan2
- CPNE6 | c.1104del p.N369Tfs*78 | Frame Shift Del (DEL) | VAF 106/366 reads (29%) | called by mutect2, varscan2
- CPS1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 55/212 reads (26%) | called by muse, mutect2, varscan2
- CRACD | c.501dup p.Q168Tfs*17 | Frame Shift Ins (INS) | VAF 62/368 reads (17%) | called by mutect2, varscan2
- CSK | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD1 | c.6061dup p.S2021Ffs*5 (on ENST00000520002; = p.S2020Ffs*5 on NM_033225.6) | Frame Shift Ins (INS) | VAF 54/209 reads (26%) | called by mutect2, varscan2
- CSMD2 | c.2918G>T p.S973I | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CT55 | c.225del p.V76Lfs*14 | Frame Shift Del (DEL) | VAF 90/248 reads (36%) | called by mutect2, varscan2
- CTC1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 97/426 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTDSP2 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 144/483 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL1 | c.28del p.H10Tfs*3 | Frame Shift Del (DEL) | VAF 88/302 reads (29%) | called by mutect2, varscan2
- CUL4B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 221/671 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CXADR | c.602del p.N201Mfs*27 | Frame Shift Del (DEL) | VAF 58/120 reads (48%) | called by mutect2, varscan2
- DDIT4L | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DDX54 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 186/704 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DEF6 | c.1069_1071del p.K357del | In Frame Del (DEL) | VAF 168/444 reads (38%) | called by mutect2, varscan2
- DEF6 | c.1788del p.S597Rfs*39 | Frame Shift Del (DEL) | VAF 149/406 reads (37%) | called by mutect2, varscan2
- DHX30 | c.2530A>G p.N844D (on ENST00000445061 / NM_138615.3; = p.N805D on NM_014966.3) | Missense Mutation (SNP) | VAF 133/347 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.2775del p.Q926Nfs*19 | Frame Shift Del (DEL) | VAF 92/262 reads (35%) | called by mutect2, varscan2
- DNAJC27 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNPEP | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 25/515 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DOC2B | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- DOLPP1 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 135/363 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DPEP3 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP10 | c.1944del p.F648Lfs*12 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- DPYSL3 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPYSL3 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 91/608 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DXO | c.399del p.H134Tfs*2 | Frame Shift Del (DEL) | VAF 203/523 reads (39%) | called by mutect2, varscan2
- E2F7 | c.2186del p.P729Lfs*53 | Frame Shift Del (DEL) | VAF 96/416 reads (23%) | called by mutect2, varscan2
- EFR3B | c.1921A>G p.R641G | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.116); called by muse, varscan2
- EIF2S3B | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 148/606 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- EIF5B | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- ELP4 | c.1012del p.T338Lfs*11 (on ENST00000350638; = p.T337Lfs*11 on NM_019040.5) | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, varscan2
- EMILIN3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 116/608 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ENOX2 | c.1270C>T p.Q424* (on ENST00000338144 / NM_001382520.1; = p.Q395* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 102/299 reads (34%) | called by muse, mutect2, varscan2
- EPB41L3 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by mutect2, varscan2
- EPRS1 | c.2986G>A p.G996R | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM124B | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 31/223 reads (14%) | called by mutect2, varscan2
- FAM178B | c.338del p.P113Rfs*31 | Frame Shift Del (DEL) | VAF 162/504 reads (32%) | called by mutect2, varscan2
- FAM189A1 | c.1280T>G p.L427R | Missense Mutation (SNP) | VAF 187/596 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FAM71A | c.1178del p.P393Lfs*12 | Frame Shift Del (DEL) | VAF 119/454 reads (26%) | called by mutect2, varscan2
- FLG2 | c.3489_3501del p.S1164Nfs*59 | Frame Shift Del (DEL) | VAF 65/320 reads (20%) | called by mutect2, varscan2
- FN1 | c.2258A>G p.E753G | Missense Mutation (SNP) | VAF 112/412 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC11 | c.786del p.V263Wfs*59 | Frame Shift Del (DEL) | VAF 172/776 reads (22%) | called by mutect2, varscan2
- FNTA | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXD4L4 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 47/1944 reads (2%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2
- FOXK1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 21/666 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- FOXN1 | c.1465del p.Q489Rfs*61 | Frame Shift Del (DEL) | VAF 216/753 reads (29%) | called by mutect2, varscan2
- GAP43 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDPD2 | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GDPGP1 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 160/574 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, varscan2
- GJA8 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 66/538 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA4 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 147/447 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GLUD1 | c.542del p.G181Vfs*29 | Frame Shift Del (DEL) | VAF 73/362 reads (20%) | called by mutect2, varscan2
- GMIP | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 133/494 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPR108 | c.1141G>A p.A381T (on ENST00000264080 / NM_001080452.1; = p.A139T on NM_020171.2) | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA4 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- GRK1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 125/499 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM7 | c.1767del p.W590Gfs*3 | Frame Shift Del (DEL) | VAF 74/234 reads (32%) | called by mutect2, varscan2
- GUCA1C | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- H3Y1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HS3ST3A1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by mutect2, varscan2
- HTT | c.7091C>T p.A2364V | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IFI16 | c.679dup p.I227Nfs*42 | Frame Shift Ins (INS) | VAF 65/236 reads (28%) | called by mutect2, varscan2
- IGSF21 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 156/593 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- IGSF9B | c.2573T>C p.F858S | Missense Mutation (SNP) | VAF 151/627 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL17C | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 204/698 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL1RAPL1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 19/545 reads (3%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.05); called by muse, mutect2
- IL31RA | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRAG2 | c.4107G>T p.W1369C (on ENST00000636465; = p.W414C on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRS1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- ITPK1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 23/598 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2
- KANK1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KANK3 | c.49del p.R17Afs*36 | Frame Shift Del (DEL) | VAF 140/441 reads (32%) | called by mutect2, varscan2
- KCMF1 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 197/652 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KCNG2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 176/418 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM6A | c.1892C>A p.P631Q | Missense Mutation (SNP) | VAF 115/382 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); called by muse, varscan2
- KIF26B | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 58/756 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIF3C | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 153/435 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLHDC7B | c.587A>T p.E196V (on ENST00000395676; = p.E837V on NM_138433.5) | Missense Mutation (SNP) | VAF 202/700 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- KLHL25 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 151/530 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KLHL26 | c.1104del p.Q369Sfs*22 | Frame Shift Del (DEL) | VAF 115/457 reads (25%) | called by mutect2, varscan2
- KMT2B | c.7688C>T p.A2563V | Missense Mutation (SNP) | VAF 130/490 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 136/488 reads (28%) | called by mutect2, varscan2
- KPNA3 | c.1310del p.N437Tfs*3 | Frame Shift Del (DEL) | VAF 107/406 reads (26%) | called by mutect2, varscan2
- KRT83 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 196/658 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- KRTAP10-8 | c.616T>C p.S206P | Missense Mutation (SNP) | VAF 210/597 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KSR2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 177/636 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAS1L | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 147/449 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LCE3E | c.242del p.G81Afs*38 | Frame Shift Del (DEL) | VAF 88/444 reads (20%) | called by mutect2, varscan2
- LEFTY2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 20/734 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LILRB4 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- LIPT1 | c.79del p.T27Qfs*2 | Frame Shift Del (DEL) | VAF 57/292 reads (20%) | called by mutect2, varscan2
- LMF1 | c.1259T>A p.I420N | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LONRF1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRP8 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 206/680 reads (30%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.638); called by muse, mutect2
- LRRC43 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 106/409 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.2812A>G p.N938D (on ENST00000651989 / NM_001370785.2; = p.N905D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- LRRC8E | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 15/591 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- LYST | c.3705G>T p.Q1235H | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.429); called by muse, mutect2
- MAGEB18 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MAGEB6B | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAML3 | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 140/524 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- MAPK1IP1L | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 128/398 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MAST1 | c.3008T>C p.V1003A | Missense Mutation (SNP) | VAF 113/379 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATN2 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATN2 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MBTPS2 | c.1138del p.S380Afs*8 | Frame Shift Del (DEL) | VAF 62/190 reads (33%) | called by mutect2, varscan2
- MCM3AP | c.3131C>A p.P1044H | Missense Mutation (SNP) | VAF 215/511 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MEGF11 | c.860C>G p.T287S | Missense Mutation (SNP) | VAF 113/446 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- METTL15 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- MIDEAS | c.3073del p.T1025Qfs*68 | Frame Shift Del (DEL) | VAF 168/548 reads (31%) | called by mutect2, varscan2
- MPLKIP | c.391dup p.R131Kfs*4 | Frame Shift Ins (INS) | VAF 42/231 reads (18%) | called by mutect2, varscan2
- MRC2 | c.3656dup p.C1220Lfs*16 | Frame Shift Ins (INS) | VAF 174/618 reads (28%) | called by mutect2, varscan2
- MRGPRE | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 80/550 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- MRPL3 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSRB2 | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTMR3 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 115/417 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTSS2 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 144/533 reads (27%) | called by muse, mutect2, varscan2
- MUC19 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- MXRA5 | c.7514T>C p.I2505T | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYH6 | c.1618A>G p.M540V | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYH7 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NBEAL1 | c.6945del p.F2315Lfs*2 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | called by mutect2, varscan2
- NCKAP5 | c.1987T>C p.S663P | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEB | c.1933_1934del p.K645Efs*6 | Frame Shift Del (DEL) | VAF 48/179 reads (27%) | called by mutect2, varscan2
- NEB | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEUROD6 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NEXMIF | c.796A>G p.S266G | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFATC4 | c.320del p.G107Vfs*96 | Frame Shift Del (DEL) | VAF 180/724 reads (25%) | called by mutect2, varscan2
- NGFR | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 204/774 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL2 | c.1923dup p.P642Tfs*44 (on ENST00000510661; = p.P1008Tfs*44 on NM_001013627.2) | Frame Shift Ins (INS) | VAF 83/235 reads (35%) | called by mutect2, varscan2
- NINL | c.1812C>T p.G604= | Splice Region (SNP) | VAF 72/199 reads (36%) | called by muse, mutect2, varscan2
- NLRP12 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 106/443 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NPAS3 | c.2171C>T p.A724V (on ENST00000356141 / NM_001164749.2; = p.A692V on NM_022123.3) | Missense Mutation (SNP) | VAF 170/584 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NPEPPS | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 242/905 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NQO1 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- NR4A1 | c.893del p.N298Tfs*36 | Frame Shift Del (DEL) | VAF 107/312 reads (34%) | called by mutect2, varscan2
- NRDE2 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 27/601 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2
- NUGGC | c.1895del p.F632Sfs*2 | Frame Shift Del (DEL) | VAF 52/216 reads (24%) | called by mutect2, varscan2
- NWD2 | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OBSL1 | c.5547C>G p.C1849W | Missense Mutation (SNP) | VAF 181/719 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR10G9 | c.753dup p.V252Cfs*? | Frame Shift Ins (INS) | VAF 65/289 reads (22%) | called by mutect2, varscan2
- PAK3 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PARD6G | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PARP4 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDH17 | c.2192dup p.R732Afs*35 | Frame Shift Ins (INS) | VAF 122/430 reads (28%) | called by mutect2, varscan2
- PCDHB5 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 167/642 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX2 | c.2998G>A p.V1000I | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX3 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 162/601 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD11 | c.3446G>A p.G1149D | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.1899_1900dup p.E634Gfs*10 | Frame Shift Ins (INS) | VAF 76/294 reads (26%) | called by mutect2, varscan2
- PGAP1 | c.2029A>G p.M677V | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGPEP1 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 112/363 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PHGR1 | c.233dup p.G79Wfs*8 | Frame Shift Ins (INS) | VAF 30/183 reads (16%) | called by mutect2, varscan2
- PIH1D2 | c.377del p.N126Ifs*3 | Frame Shift Del (DEL) | VAF 48/184 reads (26%) | called by mutect2, varscan2
- PITPNM3 | c.1137del p.P380Rfs*139 | Frame Shift Del (DEL) | VAF 70/492 reads (14%) | called by mutect2, varscan2
- PKD1L1 | c.7801C>A p.L2601I | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PLAU | c.773del p.N258Tfs*22 | Frame Shift Del (DEL) | VAF 134/456 reads (29%) | called by mutect2, varscan2
- PLD6 | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 30/602 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- PLEKHG4B | c.3237G>T p.Q1079H (on ENST00000283426; = p.Q1435H on NM_052909.5) | Missense Mutation (SNP) | VAF 131/455 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PLXNA4 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PNPT1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PODN | c.1670C>T p.A557V (on ENST00000395871; = p.A509V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- POLR3E | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- POMGNT1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 15/434 reads (3%) | PolyPhen benign (0.351); called by muse, mutect2
- POTEB3 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- POU3F3 | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 171/625 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- POU5F2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 27/494 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- PPL | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 123/474 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- PPM1L | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PPP1R3D | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 29/975 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PRDM4 | c.2202del p.K734Nfs*7 | Frame Shift Del (DEL) | VAF 70/259 reads (27%) | called by mutect2, varscan2
- PRKCB | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 159/627 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROB1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 222/735 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS48 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2
- PTAFR | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 107/432 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1223del p.K408Sfs*14 (on ENST00000421990 / NM_001136042.2; = p.K390Sfs*14 on NM_025267.3) | Frame Shift Del (DEL) | VAF 74/386 reads (19%) | called by mutect2, varscan2
- PWWP3A | c.92dup p.N31Kfs*2 (on ENST00000627377; = p.N30Kfs*2 on NM_032853.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 68/278 reads (24%) | called by mutect2, varscan2
- PYGO2 | c.448del p.Q150Rfs*11 | Frame Shift Del (DEL) | VAF 139/470 reads (30%) | called by mutect2, varscan2
- QPRT | c.157del p.V53Yfs*116 | Frame Shift Del (DEL) | VAF 198/733 reads (27%) | called by mutect2, varscan2
- RABGGTA | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 92/387 reads (24%) | called by muse, mutect2, varscan2
- RASGRF1 | c.2184del p.K729Sfs*31 | Frame Shift Del (DEL) | VAF 113/560 reads (20%) | called by mutect2, varscan2
- RBFOX3 | c.21del p.A8Pfs*38 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, varscan2
- RBM44 | c.776del p.N259Mfs*5 (on ENST00000611254; = p.N893Mfs*5 on NM_001080504.2) | Frame Shift Del (DEL) | VAF 29/147 reads (20%) | called by mutect2, varscan2
- RBM46 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- REXO5 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RICTOR | c.3182del p.F1061Sfs*19 | Frame Shift Del (DEL) | VAF 42/172 reads (24%) | called by mutect2, varscan2
- RILP | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 159/556 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RIPOR3 | c.527T>G p.L176R | Missense Mutation (SNP) | VAF 191/846 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RNF113B | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- RNF2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RP1 | c.4941del p.P1648Lfs*62 | Frame Shift Del (DEL) | VAF 44/150 reads (29%) | called by mutect2, varscan2
- RPAP2 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPUSD4 | c.958del p.L320Ffs*8 | Frame Shift Del (DEL) | VAF 116/470 reads (25%) | called by mutect2, varscan2
- RRAS | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 169/552 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RRP12 | c.3293G>T p.R1098L | Missense Mutation (SNP) | VAF 86/705 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by mutect2, varscan2
- RTP2 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.275); called by muse, mutect2
- SAMD9 | c.153del p.E52Nfs*16 | Frame Shift Del (DEL) | VAF 86/276 reads (31%) | called by mutect2, varscan2
- SCFD1 | c.1189del p.R397Dfs*14 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | called by mutect2, varscan2
- SCX | c.476del p.P159Rfs*31 | Frame Shift Del (DEL) | VAF 149/540 reads (28%) | called by mutect2, varscan2
- SCYL1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 166/547 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SEPTIN9 | c.328C>A p.L110M (on ENST00000427177 / NM_001113491.2; = p.L92M on NM_006640.4) | Missense Mutation (SNP) | VAF 147/818 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SERPINA3 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 143/371 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SET | c.793G>T p.G265W (on ENST00000372692 / NM_001374326.1; = p.G252W on NM_003011.4) | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SETBP1 | c.3737A>C p.K1246T | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHCBP1L | c.778del p.Y260Mfs*84 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, varscan2
- SLC26A7 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SLC35A4 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 156/594 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLCO5A1 | c.663del p.Y222Tfs*6 | Frame Shift Del (DEL) | VAF 135/425 reads (32%) | called by mutect2, varscan2
- SOGA3 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORBS2 | c.2938del p.I980Sfs*45 (on ENST00000284776 / NM_021069.5; = p.I546Sfs*45 on NM_003603.6) | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by mutect2, varscan2
- SPAG5 | c.16_17insT p.K6Ifs*23 | Frame Shift Ins (INS) | VAF 138/492 reads (28%) | called by mutect2, varscan2
- SPATA5 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- SPECC1 | c.47del p.G16Afs*17 | Frame Shift Del (DEL) | VAF 140/465 reads (30%) | called by mutect2, varscan2
- SPEG | c.2747T>C p.F916S | Missense Mutation (SNP) | VAF 30/714 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.069); called by muse, mutect2
- SPEG | c.8563G>A p.A2855T | Missense Mutation (SNP) | VAF 181/605 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOCD1 | c.1159T>C p.C387R | Missense Mutation (SNP) | VAF 139/481 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK24 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- STRC | c.2159G>T p.R720M | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- SUGP1 | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 164/562 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SYNPR | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TAF7L | c.719del p.K240Rfs*26 | Frame Shift Del (DEL) | VAF 99/278 reads (36%) | called by mutect2, varscan2
- TAP2 | c.1159del p.V387Cfs*4 | Frame Shift Del (DEL) | VAF 123/288 reads (43%) | called by mutect2, varscan2
- TAPBP | c.392_393del p.P131Rfs*82 | Frame Shift Del (DEL) | VAF 176/677 reads (26%) | called by mutect2, varscan2
- TBR1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TERF2IP | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 159/595 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TEX13A | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 184/528 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TGFBI | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- THOC1 | c.1291del p.I431Ffs*2 | Frame Shift Del (DEL) | VAF 68/323 reads (21%) | called by mutect2, varscan2
- THSD1 | c.1804dup p.R602Kfs*57 | Frame Shift Ins (INS) | VAF 142/478 reads (30%) | called by mutect2, varscan2
- TLL1 | c.223dup p.I75Nfs*3 | Frame Shift Ins (INS) | VAF 30/152 reads (20%) | called by mutect2, varscan2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 64/252 reads (25%) | called by mutect2, varscan2
- TMC8 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 234/782 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM131 | c.5090A>G p.D1697G | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TMEM178B | c.773del p.G258Afs*14 | Frame Shift Del (DEL) | VAF 104/320 reads (33%) | called by mutect2, varscan2
- TMEM59 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOX2 | c.914del p.P305Qfs*34 (on ENST00000358131 / NM_001098798.2; = p.P281Qfs*34 on NM_032883.3) | Frame Shift Del (DEL) | VAF 97/373 reads (26%) | called by mutect2, varscan2
- TRABD2B | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM23 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM41 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 158/545 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, varscan2
- TRIM42 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM56 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 150/597 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.546); called by muse, mutect2
- TRIML2 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 153/540 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIT1 | c.662T>C p.F221S | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- TRRAP | c.8533G>T p.G2845C (on ENST00000359863 / NM_001244580.1; = p.G2827C on NM_003496.3) | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by mutect2, varscan2
- TSPAN9 | c.484del p.E162Rfs*33 | Frame Shift Del (DEL) | VAF 122/416 reads (29%) | called by mutect2, varscan2
- TTLL7 | c.2619G>T p.M873I | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.69371A>C p.E23124A (on ENST00000591111; = p.E15700A on NM_003319.4) | Missense Mutation (SNP) | VAF 33/261 reads (13%) | PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TTN | c.40035del p.K13345Nfs*30 (on ENST00000591111; = p.K5921Nfs*30 on NM_003319.4) | Frame Shift Del (DEL) | VAF 64/238 reads (27%) | called by mutect2, varscan2
- TTN | c.19490T>C p.F6497S (on ENST00000591111; = p.F5570S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/337 reads (24%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUSC1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 148/406 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, varscan2
- U2SURP | c.3015del p.K1005Nfs*30 | Frame Shift Del (DEL) | VAF 105/371 reads (28%) | called by mutect2, varscan2
- ULK1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- UPF1 | c.2504C>T p.A835V (on ENST00000599848 / NM_001297549.2; = p.A824V on NM_002911.4) | Missense Mutation (SNP) | VAF 130/436 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP10 | c.30dup p.G11Wfs*4 | Frame Shift Ins (INS) | VAF 35/133 reads (26%) | called by mutect2, varscan2
- USP17L7 | c.106_108del p.S36del | In Frame Del (DEL) | VAF 94/572 reads (16%) | called by mutect2, varscan2
- VAMP7 | c.547T>C p.C183R | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- WDR33 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WNK2 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 162/390 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- WNT3A | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 147/520 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | called by mutect2, varscan2
- ZCCHC24 | c.554G>A p.W185* | Nonsense Mutation (SNP) | VAF 120/437 reads (27%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.159A>G p.I53M | Missense Mutation (SNP) | VAF 135/555 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ZNF106 | c.746_760del p.N249_C254delinsS | In Frame Del (DEL) | VAF 48/256 reads (19%) | called by mutect2, varscan2
- ZNF2 | c.357del p.K119Nfs*6 (on ENST00000611147 / NM_001291605.2; = p.K106Nfs*6 on NM_021088.4) | Frame Shift Del (DEL) | VAF 105/410 reads (26%) | called by mutect2, varscan2
- ZNF214 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ZNF578 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF69 | c.386T>G p.F129C (on ENST00000429654 / NM_001364730.1; = p.F115C on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by mutect2, varscan2
- ZNF732 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNF771 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 168/589 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZNF865 | c.2351del p.G784Vfs*25 | Frame Shift Del (DEL) | VAF 120/634 reads (19%) | called by mutect2, varscan2
- ZSCAN23 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ZXDA | c.305C>G p.T102S | Missense Mutation (SNP) | VAF 220/592 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZXDA | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, varscan2
- ZZEF1 | c.6899A>G p.D2300G | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AAR2 | c.849G>A p.R283= | Silent (SNP) | VAF 121/555 reads (22%) | called by muse, mutect2, varscan2
- AARS2 | c.1074G>A p.V358= | Silent (SNP) | VAF 110/295 reads (37%) | called by muse, mutect2, varscan2
- ABCA4 | c.1200C>T p.Y400= | Silent (SNP) | VAF 110/358 reads (31%) | catalogued as COSV64678228; called by muse, mutect2, varscan2
- ABCA6 | c.21C>T p.S7= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as rs866698505, COSV99446058; called by muse, mutect2, varscan2
- ABLIM1 | c.207C>T p.C69= | Silent (SNP) | VAF 17/303 reads (6%) | called by muse, mutect2
- AC008687.4 | c.201C>T p.F67= | Silent (SNP) | VAF 169/603 reads (28%) | called by muse, mutect2, varscan2
- ADAM23 | c.1626C>T p.D542= | Silent (SNP) | VAF 89/320 reads (28%) | called by muse, mutect2, varscan2
- ADCY7 | c.1386G>A p.P462= | Silent (SNP) | VAF 134/471 reads (28%) | catalogued as rs749429980, COSV54270542; called by muse, mutect2, varscan2
- AGBL1 | c.1407C>T p.D469= | Silent (SNP) | VAF 69/301 reads (23%) | catalogued as rs755745838, COSV101222163; called by muse, mutect2, varscan2
- AGO2 | c.45G>A p.P15= | Silent (SNP) | VAF 95/358 reads (27%) | catalogued as rs141930048, COSV55050947; called by muse, mutect2, varscan2
- ALDH18A1 | c.360A>G p.V120= | Silent (SNP) | VAF 62/621 reads (10%) | called by muse, mutect2, varscan2
- ANKRD27 | c.681C>T p.Y227= | Silent (SNP) | VAF 85/367 reads (23%) | catalogued as rs200412555, COSV60133166; called by muse, mutect2, varscan2
- ANKRD9 | c.570C>T p.G190= | Silent (SNP) | VAF 174/554 reads (31%) | catalogued as rs1216155926; called by muse, varscan2
- ANO3 | c.96G>A p.P32= | Silent (SNP) | VAF 93/406 reads (23%) | catalogued as rs780379245, COSV99882791; called by muse, mutect2, varscan2
- APOBR | c.618G>A p.T206= | Silent (SNP) | VAF 170/851 reads (20%) | catalogued as rs375319220; called by muse, mutect2, varscan2
- ARAF | c.1314T>C p.H438= | Silent (SNP) | VAF 27/433 reads (6%) | called by muse, mutect2
- ARFGEF2 | c.3276C>T p.R1092= | Silent (SNP) | VAF 25/565 reads (4%) | called by muse, mutect2
- ARMC5 | c.1149A>G p.A383= | Silent (SNP) | VAF 150/511 reads (29%) | catalogued as rs371292365; called by muse, mutect2, varscan2
- ARMC5 | c.1734C>A p.A578= | Silent (SNP) | VAF 209/775 reads (27%) | called by muse, mutect2, varscan2
- ARSD | c.1278T>C p.G426= | Silent (SNP) | VAF 152/391 reads (39%) | called by muse, mutect2, varscan2
- B3GALT1 | c.957A>G p.S319= | Silent (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- BAG3 | c.1647C>A p.T549= | Silent (SNP) | VAF 183/598 reads (31%) | called by muse, mutect2, varscan2
- BARHL2 | c.267C>T p.H89= | Silent (SNP) | VAF 233/782 reads (30%) | called by muse, mutect2, varscan2
- BCL2 | c.621G>A p.R207= | Silent (SNP) | VAF 99/303 reads (33%) | catalogued as rs754454655, COSV61379668; called by muse, mutect2, varscan2
- BCL2L14 | c.45T>C p.D15= | Silent (SNP) | VAF 46/446 reads (10%) | called by muse, mutect2, varscan2
270 further variants in this file (0 protein-altering or splice-affecting, 221 silent, 49 other) are not listed here.
